Somatic mutation profile of tumor specimen 0DPX3W from CCDI case PBCEFP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Dysembryoplastic neuroepithelial tumor; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 4.3 years (1,560 days).
Specimen 0DPX3W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7ca8f24-93c0-444b-bcf9-3ddc187d90ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPX3B (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af82b9c8-964f-475d-96c0-daa4c5ac7551

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Frame Shift Del 2, Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDGFRA | c.1153A>T p.K385* | Nonsense Mutation (SNP) | VAF 59/240 reads (25%) | catalogued as COSV57275352; called by muse, mutect2, varscan2
- PDGFRA | c.1154A>T p.K385M | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57264818; called by muse, mutect2, varscan2
- FYCO1 | c.2410del p.D804Mfs*10 | Frame Shift Del (DEL) | VAF 25/117 reads (21%) | called by mutect2, pindel
- SHANK1 | c.3256del p.Q1086Sfs*257 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel
- AQP7 | c.743+70del | Intron (DEL) | VAF 6/54 reads (11%) | catalogued as rs1377039376; called by pindel, varscan2
- CCDC33 | c.2139+155C>A | Intron (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- CHMP1A | c.8-14del | Intron (DEL) | VAF 10/95 reads (11%) | catalogued as rs1308134072; called by mutect2, pindel
